Somatic mutation profile of tumor specimen TCGA-MA-AA43-01A (aliquot TCGA-MA-AA43-01A-11D-A42O-09) from TCGA case TCGA-MA-AA43, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.3 years (17,658 days).
Specimen TCGA-MA-AA43-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84b802b7-10fa-4d61-9c37-b709ce786032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA43-10A (Blood Derived Normal), aliquot TCGA-MA-AA43-10A-01D-A45U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60a40fe6-0487-401e-aa0c-cc068be16c64

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, Nonsense Mutation 5, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99256953; called by muse, mutect2, varscan2
- ADAT2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757765963, COSV99395855; called by muse, mutect2, varscan2
- ADGRA1 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs373692628; called by muse, mutect2, varscan2
- BCAR3 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as rs373868471, COSV53073974; called by muse, mutect2, varscan2
- BDKRB1 | c.1021T>A p.S341T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as COSV99387941; called by muse, mutect2
- C10orf62 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs768730543, COSV101035282; called by muse, mutect2, varscan2
- CHRNA3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs200528785, COSV58774659; called by muse, mutect2, varscan2
- COL16A1 | c.4112G>A p.G1371E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766330027, COSV99594906; called by muse, mutect2, varscan2
- CPSF1 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs782691908, COSV100450572; called by muse, mutect2
- DHX37 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs141344600; called by muse, mutect2, varscan2
- DICER1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as COSV100602276; called by muse, mutect2, varscan2
- ECSIT | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1568400684, COSV99369139; called by muse, mutect2, varscan2
- EDEM2 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780339064, COSV100993805; called by muse, mutect2
- FAM47A | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV60497654; called by muse, mutect2, varscan2
- HEXIM2 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs947856275, COSV100217943; called by muse, mutect2, varscan2
- HS3ST5 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as rs374141405; called by muse, mutect2, varscan2
- IGF2BP3 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51682519, COSV99325595, COSV99325815; called by muse, mutect2, varscan2
- LAMA1 | c.7078C>T p.R2360C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs765870262, COSV67534647; called by muse, mutect2, varscan2
- MOCOS | c.2540A>T p.H847L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1356640228, COSV99733632; called by muse, mutect2, varscan2
- MYO5B | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99545696; called by muse, mutect2, varscan2
- NUP210 | c.5377G>A p.G1793S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs748602696, COSV99596557; called by muse, mutect2, varscan2
- NWD1 | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100343137; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- PDE10A | c.2147G>T p.R716I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100605321; called by muse, mutect2, varscan2
- PDE9A | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99371850; called by muse, mutect2, varscan2
- PI4KB | c.682C>T p.Q228* (on ENST00000368873 / NM_001369623.1; = p.Q240* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99649921; called by muse, mutect2, varscan2
- PIGM | c.188C>G p.T63R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100928051; called by muse, mutect2, varscan2
- PLA2G3 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as rs756453067, COSV53207704, COSV99311769; called by muse, mutect2, varscan2
- PLEKHN1 | c.1405G>A p.E469K (on ENST00000379409; = p.E417K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.926); catalogued as COSV100379206; called by muse, mutect2, varscan2
- PML | c.1015T>A p.Y339N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167527; called by muse, mutect2
- PREP | c.1120-2A>G p.X374_splice (on ENST00000369110; = p.X440_splice on NM_002726.5) | Splice Site (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100964083; called by muse, mutect2, varscan2
- REST | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100471163; called by muse, mutect2, varscan2
- ROBO1 | c.2675A>G p.D892G | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as COSV101458996, COSV101459060; called by muse, mutect2, varscan2
- RP1L1 | c.3479G>A p.G1160E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV101223414; called by muse, mutect2, varscan2
- RPF1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs1481722251, COSV101039787; called by muse, mutect2, varscan2
- SENP6 | c.1355T>G p.V452G | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100519333; called by muse, mutect2, varscan2
- SIGLEC11 | c.1142T>A p.V381D | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101389480; called by muse, mutect2, varscan2
- SIN3B | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV99931868; called by muse, mutect2, varscan2
- SLC27A3 | c.2114G>A p.G705E (on ENST00000271857; = p.G577E on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670035; called by muse, mutect2, varscan2
- STK32C | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100062956; called by muse, mutect2, varscan2
- TBX22 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV64787178; called by muse, mutect2, varscan2
- TG | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs760105184, COSV99601920; called by muse, mutect2, varscan2
- TTN | c.13553T>A p.L4518H (on ENST00000591111; = p.L3591H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | PolyPhen possibly damaging (0.614); catalogued as COSV100620499; called by muse, mutect2, varscan2
- UBA1 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.341); catalogued as rs1218465518, COSV100255858; called by muse, mutect2, varscan2
- VAC14 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55751249, COSV55752959; called by muse, mutect2, varscan2
- WDR25 | c.1230G>T p.W410C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100091997; called by muse, mutect2, varscan2
- ADGRV1 | c.18485del p.P6162Lfs*2 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4042G>A p.E1348K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- CIBAR1 | c.739_751del p.R247Lfs*15 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by pindel, varscan2
- GGCX | c.1547dup p.L516Ffs*13 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- OR10A4 | c.8G>C p.W3S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1D | c.774C>T p.D258= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs780403284, COSV63808767; called by muse, mutect2, varscan2
- DNAH10 | c.4581G>A p.T1527= (on ENST00000409039; = p.T1466= on NM_207437.3) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1019450402, COSV68997117; called by muse, mutect2, varscan2
- FSHB | c.78C>T p.I26= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV54221584, COSV99569479; called by muse, mutect2, varscan2
- GAS2L2 | c.1293C>T p.D431= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs142059348; called by muse, mutect2, varscan2
- GMEB2 | c.1158G>A p.P386= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs778865423, COSV99823718; called by muse, mutect2, varscan2
- KIRREL2 | c.1869C>T p.L623= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV52878557; called by muse, mutect2, varscan2
- MIPOL1 | c.795A>C p.A265= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100539238; called by muse, mutect2, varscan2
- PCDHB8 | c.1962G>A p.S654= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as rs782208929, COSV99177148; called by muse, varscan2
- SEC14L5 | c.1677G>A p.R559= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99229163; called by muse, mutect2, varscan2
- SLC5A9 | c.141C>T p.F47= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs767249431, COSV52582881; called by muse, mutect2, varscan2
- SSTR4 | c.342C>T p.F114= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs767915860, COSV54797472, COSV54798666; called by muse, mutect2, varscan2
- TMEM132B | c.2757C>T p.C919= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs200940370; called by muse, mutect2, varscan2
- USP19 | c.660C>T p.L220= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100026324; called by muse, varscan2
- MIR517C | n.26G>A | RNA (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2
- MSL3 | c.1171+20C>T | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100384951; called by muse, mutect2, varscan2
- UVSSA | c.*9827G>A | 3'UTR (SNP) | VAF 23/101 reads (23%) | catalogued as rs746348588, COSV100246238; called by muse, mutect2, varscan2
